CCDI case PBBSFA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/6cc70508-a5ed-4d65-b60f-63909e4100ee

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Eyelid; Age at diagnosis: 3.4 years (1,250 days).

Biospecimens (3 samples)
- Sample 0DFSQJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFSS1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFSSH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
